CCDI case PBCAZM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/4142874f-a462-48ef-80a5-b5443d94e765

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Sertoli cell tumor, NOS: ICD-O-3 morphology code: 8640/1; Tissue or organ of origin: Ovary; Age at diagnosis: 4.0 years (1,447 days).

Biospecimens (3 samples)
- Sample 0DNJA2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNJAC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNJB8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
